Surgical pathology report (de-identified scan), TCGA case TCGA-B8-5163, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma), tissue source site UNC, specimen TCGA-B8-5163-01A (Primary Tumor).

[page 1 of 3]
Surgical Pathology Report

Diagnosis:

Right kidney, radical nephrectomy

Histologic tumor type/subtype: renal cell carcinoma, clear cell subtype; see comment.

Histologic grade (if applicable): Fuhrman grade 3 of 4

Tumor size (greatest dimension): 5.5 cm

Extent of tumor invasion:

Capsular invasion/perirenal adipose tissue: tumor focally invades capsule; perirenal adipose tissue is negative for carcinoma

Gerota's fascia: negative for carcinoma

Renal vein: positive for carcinoma

Ureter: negative for carcinoma

Venous (large vessel): positive for carcinoma

Lymphatic (small vessel): positive for carcinoma

Histologic assessment of surgical margins:

Perirenal adipose tissue: negative for carcinoma

Gerota's fascia: negative for carcinoma

Renal vein: positive for carcinoma

Renal artery: negative for carcinoma

Ureter: negative for carcinoma

Adrenal gland: not present

Lymph nodes: none identified

Other significant findings: Mild glomerulosclerosis and interstitial fibrosis.

AJCC Staging:

pT3a

pNx

This staging information is based on information available at the time of this report, and is subject to change pending clinical review and additional information.

Comment:

Immunohistochemical stains are performed and demonstrate the tumor is negative for Hales colloidal iron, CK7, CD117, and RCC while being positive for vimentin and with equivocal staining for E-cadherin. The histologic and immunohistochemical findings are most consistent with renal cell carcinoma, clear cell subtype.

Clinical History:

with a clinical diagnosis of a renal tumor. As, the patient has a large right upper pole renal mass that extends to the left renal vein and into the inferior vena cava.

[page 2 of 3]
Gross Description:

Received is one appropriately labeled container.

Specimen fixation: formalin

Type of specimen: radical

Side of specimen: right

Size and weight of specimen: The weight is 930 grams; the specimen measures 26.5 x 16.0 x 9.5 cm overall; the kidney measures 9.2 x 6.0 x 5.0 cm.

Orientation: The perirenal adipose tissue has been previously inked blue.

Presence/absence of adrenal gland: absent

Tumor description/site: Anatomic site: renal cortex; upper pole; The pole varies from yellow to red to dark brown with focal cysts and necrosis evident. The tumor is encapsulated and extends to the hilar areas and through the renal vein.

Tumor size: 5.5 x 4.7 x 4.0 cm

Presence/absence of multicentricity: absent

Confinement/non-confinement to the kidney: The tumor is predominantly confined to the cortex of the kidney and is seen extending into and through the lumen of the renal vein.

Extent of invasion:

Perirenal adipose tissue: tumor does not grossly involve

Gerota's fascia: tumor does not grossly involve

Renal vein: positive for gross tumor

Ureter: does not grossly involve

Other organs: n/a

Surgical margins:

Perirenal adipose tissue: negative, 0.5 cm at closest approach

Renal vein: positive, A portion of polypoid tumor grossly extends through the lumen and measures 2.5 x 1.5 x 1.0 cm.

Renal artery: negative, 0.3 cm at closest approach

Ureter: negative, 1.5 cm at closest approach

Description of kidney away from tumor: The remainder of the kidney appears red to tan in color with no other lesions or masses identified; The average cortical measurement is 0.8 cm and the average medullary measurement is 1.2 cm.

Lymph nodes (hilar): none identified

Other significant findings: none

Tissue submitted for special investigations: yes

Digital photograph taken: no

Block summary:

(Inking: blue=perirenal fat)

[page 3 of 3]
A1 - ureter and artery margin
A2 - tumor and perirenal fat, closest approach
A3-A7 - tumor with capsule
A8 - central tumor
A9 - tumor with overlying perirenal fat, additional section
A10-A11 - perpendicular section through tumor extension into renal vein (at hilum)
A12 - hilum, en face
A13 - hilum, perpendicular sections
A14 - normal kidney and urothelium
A15 - ureter, additional

Grossing Pathologist:

Light Microscopy:

Light microscopic examination is performed.

Appropriate internal and/or external positive and negative controls have been evaluated. Some of the immunohistochemical reagents used in this case may be classified as analyte specific reagents (ASR). These were developed and have performance characteristics determined by the [REDACTED], [REDACTED]. These reagents have not been cleared or approved by the US Food and Drug Administration (FDA). The FDA has determined that such clearance or approval is not necessary. These tests are used for clinical purposes. They should not be regarded as investigational or for research. This laboratory is certified under the Clinical Laboratory Improvement Amendments of [REDACTED] (CLIA-88) as qualified to perform high complexity clinical laboratory testing.

[REDACTED]

Source: NCI Genomic Data Commons file 5ecb0c09-71d8-494a-b140-b90efbcb04c2 (TCGA-B8-5163.4E7CFBAB-7E98-4E75-9EEF-6AD8316A38F5.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).